Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A8I1, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A8I1-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Clinical Case Report

(For Collection of Cancerous Tissue)

ICD O-3
Carcinoma, squamous cell NOS
Site Esophagus NOS
Esophagus, middle third
12/11/2013

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	VIETNAMESE	
☐ Male ☒ Female		☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			121/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Trouble Swallowing
Symptoms: Weight loss
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status	Date of First Menses	# of Pregnancies	
☐ Pre-menopausal			
☐ Peri-Menopausal		# of Live Births	
☒ Post-menopausal			
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD		☐ Hormone Replacement Therapy:	
☐ Other:			

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:		
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:		
Hep C	☒ Negative ☐ Positive:		CA 19-9	☐ Negative ☐ Positive:		
AFP	☐ Negative ☐ Positive:		PSA	☐ Negative ☐ Positive:		
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the oesophagus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N0 M0 Stage: IIA		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Resection of the upper part of oesophagus		
Primary Tumor		
Organ	Detailed Location	Size
Esophagus Tumor	middle third	6 x 5 x 1.5 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 2 N 0 M 0		Stage: I A

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: .

___ Date:

_Time: _

Preserved by: .

___ Date:

_Time: _

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
ERB plagues tumor	6 x 5 x 1.5 cm	middle third	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2	N 0	M 0	Stage: II
Notes:			

[page 5 of 5]
IRB APPROVED

Consolidated Pathology Diagnosis

Cell Distribution			Structural Pattern		
	+	-		+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis	X		Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	X		Glandular cell			Round Cell			Large Cell		
Spindle Cell	X		Cell Stratification			Fibroblast			Small Cell		
Keratin	X		Secretion			Osteoblast			RS Cell/RS Like		
Desmosome	X		Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl		X	Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: ☐ Well ☐ Moderate ☐ Poor

Nuclear Atypia:	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				

Nuclear Grade:

D₁ 80% D₂ 80% D₃ 75% D₄ 80% Necrosis 1%

Final Pathology Report

Histological Diagnosis: Squamous Cell Carcinoma **Grade:** 3

Comments:

M₁, M₂: Chronic Lymphocyticitis

Director, Research Pathology

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS - PC

Date

Source: NCI Genomic Data Commons file f6f625f2-1a29-4b39-bc6c-28277ba79e35 (TCGA-LN-A8I1.01727F86-5A8C-4324-BDA4-E47DD7629C19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).